CCDI case PBCLNX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/13e40f03-fbf1-4d43-9c42-8cb4727a0863

Demographics
Sex at birth: male; Race: american indian or alaska native.

Diagnoses (1)
1. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 9.8 years (3,579 days).

Biospecimens (3 samples)
- Samples 0DUQYQ, 0DUQYX (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUR04: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
